Surgical pathology report (de-identified scan), TCGA case TCGA-61-1918, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1918-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –

ADIPOSE TISSUE WITH MESOTHELIAL PROLIFERATION AND FOCAL FIBROSIS, NO TUMOR SEEN.

PART 2: OVARY, FALLOPIAN TUBE, RIGHT SALPINGO-OOPHORECTOMY –

- A. FALLOPIAN TUBE WITH MESOTHELIAL HYPERPLASIA OF PERITONEAL SURFACE.
- B. OVARY WITH POORLY DIFFERENTIATED ADENOCARCINOMA WITH FOCAL PAPILLARY SEROUS DIFFERENTIATION.
- C. MATURE CYSTIC TERATOMA.

PART 3: BLADDER, SEROSA, EXCISION –

DENSE FIBROUS TISSUE WITH INFILTRATING POORLY DIFFERENTIATED CARCINOMA.

PART 4: LEFT OVARY AND FALLOPIAN TUBE –

- A. FALLOPIAN TUBE WITH PARATUBAL CYST.
- B. POORLY DIFFERENTIATED CARCINOMA WITH FOCAL PAPILLARY SEROUS DIFFERENTIATION.

PART 5: CUL-DE-SAC –

FIBROUS TISSUE WITH METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA.

PART 6: SIGMOID SEROSA, BIOPSY –

FIBROUS TISSUE WITH METASTATIC POORLY DIFFERENTIATED SEROUS CARCINOMA.

PART 7: UTERUS, 202 GRAMS, TOTAL ABDOMINAL HYSTERECTOMY –

- A. CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA, PARAKERATOSIS AND NABOTHIAN CYST.
- B. PROLIFERATIVE ENDOMETRIUM.
- C. METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA TO SEROSAL SURFACE OF THE UTERUS.
- D. INTRAMURAL LEIOMYOMATA, 3.3 CM IN DIAMETER.

PART 8: LYMPH NODE, PELVIC, LEFT –

POSITIVE FOR METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA.

PART 9: APPENDIX, APPENDECTOMY –

VERMIFORM APPENDIX WITH METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA OF SEROSAL SURFACE.

PART 10: UMBILICUS, EXCISION –

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA OF SUBCUTANEOUS TISSUE.

[page 2 of 2]
SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

A. Laterality: 3

Right 2. Left 3. Bilateral

B. Procedure: 4

1. Cystectomy 4. TAH with salpingo-oophorectomy

2. Salpingo-oophorectomy 5. Other

3. Bilateral salpingo-oophorectomy

C. Tumor size (maximum dimension): 5.5 cm

D. Histologic type: 1

1. Papillary serous tumor, [redacted]

2. Papillary serous carcinoma

3. Mucinous tumor, [redacted]

4. Mucinous carcinoma

5. Endometrioid tumor, [redacted]

6. Endometrioid carcinoma

7. Clear cell tumor, [redacted]

8. Clear cell carcinoma

9. Brenner tumor, [redacted]

10. Malignant Brenner tumor

11. Malignant mixed Müllerian tumor

12. Undifferentiated Carcinoma

13. Small cell carcinoma

14. Mature teratoma

15. Immature teratoma

16. Dysgerminoma

17. Embryonal carcinoma

18. Yolk sac tumor

19. Granulosa cell tumor, Juvenile

20. Granulosa cell tumor, adult

21. Malignant lymphoma

22. Others

E. Histologic Grade: 3

1. Well

2. Moderate

3. Poorly differentiated

F. Vascular Invasion: 1

1. Yes

2. No

G. Tumor capsule: 2

1. Intact

2. Ruptured

H. Surface implants: 1

1. Invasive

2. Non-invasive

3. Not present

I. Surface implants:

I1. Uterus: 1

1. Yes

2. No

I2. Fallopian tubes: 1

1. Yes

2. No

I3. Omentum: 2

1. Yes

2. No

I4. Peritoneal metastasis beyond the pelvis: 2

1. Microscopic

2. Less than 2 cms

3. More than 2 cms

J. Associated other lesion: NA

1. Endometriosis.

2. Abnormalities of surface epithelium or surface epithelial inclusion.

3. Others.

K. Malignant cells in ascites or peritoneal washing: 1

1. Yes

2. No

L. Nodes Involved: 1

L1. Number of positive lymph nodes: 1

L2. Total number of lymph nodes examined: 1

L3. Pelvic:

Right: # positive/total #

Left: # positive/total #

L4. Obturator:

Right: # positive/total #

Left: # positive/total #

L5. Common iliac:

Right: # positive/total #

Left: # positive/total #

L6. External iliac:

Right: # positive/total #

Left: # positive/total #

L7. Para-aortic:

Right: # positive/total #

Left: # positive/total #

L8. Inguinal:

Right: # positive/total #

Left: # positive/total #

M. Extracapsular lymph node spread

2. No

N. TNM Stage: T 4 N 1 M x

O. FIGO Stage: IV

Source: NCI Genomic Data Commons file a3b42f96-84bb-4dc3-8e8a-f4ac537a8fd5 (TCGA-61-1918.6C95BD12-E871-4E4E-961F-09A64C1FE2DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).